MMRF case MMRF_1408 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/fca8ab62-4857-4bb0-9b24-a2d14b888067

Demographics
Sex at birth: female; Race: white; Ethnicity: hispanic or latino; Age at index: 62 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 62.8 years (22,934 days); ISS stage: I; Days to last known disease status: 1,430 days (3.9 years); Days to last follow up: 1,430 days (3.9 years).
   Treatment given: Therapeutic agents: Bortezomib + Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 96 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 101 days.
   Treatment given: Therapeutic agents: Cyclophosphamide + Dexamethasone + Other; Regimen or line of therapy: First line of therapy; Days to treatment start: 121 days; Days to treatment end: 121 days.
   Treatment given: Therapeutic agents: Melphalan; Regimen or line of therapy: First line of therapy; Days to treatment start: 272 days; Days to treatment end: 272 days.
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: First line of therapy; Days to treatment start: 273 days; Days to treatment end: 273 days.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day 1 (ECOG 1): M Protein 3.84 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.405 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.81 mg/dL; Immunoglobulin G 41.8 g/L; Immunoglobulin A 0.15 g/L; Immunoglobulin M 0.09 g/L; Beta 2 Microglobulin 1.77 µg/mL; Lactate Dehydrogenase 1.78 µkat/L; Hemoglobin 7.81 mmol/L; Leukocytes 9.4 ×10⁹/L; Absolute Neutrophil 7.1 ×10⁹/L; Platelets 345 ×10⁹/L; Creatinine 54.8 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.28 mmol/L; Albumin 38 g/L; Total Protein 9.8 g/dL; Glucose 5.89 mmol/L.
- Day 96 (ECOG 1): M Protein 0.58 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.583 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.69 mg/dL; Immunoglobulin G 8.35 g/L; Immunoglobulin A 0.42 g/L; Immunoglobulin M 0.15 g/L; Lactate Dehydrogenase 7.68 µkat/L; Hemoglobin 7.87 mmol/L; Leukocytes 8 ×10⁹/L; Absolute Neutrophil 5 ×10⁹/L; Platelets 248 ×10⁹/L; Creatinine 44.2 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.25 mmol/L; Albumin 38 g/L; Total Protein 6.3 g/dL; Glucose 4.13 mmol/L.
- Day 177 (ECOG 1): M Protein 0.27 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.92 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.69 mg/dL; Immunoglobulin G 10.5 g/L; Immunoglobulin A 1.71 g/L; Immunoglobulin M 0.28 g/L; Beta 2 Microglobulin 3.33 µg/mL; Lactate Dehydrogenase 3.53 µkat/L; Hemoglobin 6.76 mmol/L; Leukocytes 5.6 ×10⁹/L; Absolute Neutrophil 3.5 ×10⁹/L; Platelets 474 ×10⁹/L; Creatinine 75.1 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.28 mmol/L; Albumin 38 g/L; Total Protein 6.7 g/dL; Glucose 5.89 mmol/L.
- Day 265 (ECOG 0): M Protein 0.46 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.73 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.18 mg/dL; Immunoglobulin G 10.5 g/L; Immunoglobulin A 0.87 g/L; Immunoglobulin M 0.27 g/L; Beta 2 Microglobulin 1.6 µg/mL; Lactate Dehydrogenase 7.7 µkat/L; Hemoglobin 8.56 mmol/L; Leukocytes 6.6 ×10⁹/L; Absolute Neutrophil 5 ×10⁹/L; Platelets 363 ×10⁹/L; Creatinine 77.8 µmol/L; Blood Urea Nitrogen 9.28 mmol/L; Calcium 2.3 mmol/L; Albumin 43 g/L; Total Protein 7.5 g/dL; Glucose 5.01 mmol/L.
- Day 364 (ECOG 1): M Protein 0.14 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.976 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.31 mg/dL; Immunoglobulin G 8.02 g/L; Immunoglobulin A 1.18 g/L; Immunoglobulin M 0.55 g/L; Lactate Dehydrogenase 2.85 µkat/L; Hemoglobin 8.06 mmol/L; Leukocytes 5.4 ×10⁹/L; Absolute Neutrophil 3.3 ×10⁹/L; Platelets 260 ×10⁹/L; Creatinine 64.5 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.38 mmol/L; Albumin 43 g/L; Total Protein 6.8 g/dL; Glucose 4.02 mmol/L.
- Day 455 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.917 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.07 mg/dL; Immunoglobulin G 10.7 g/L; Immunoglobulin A 0.87 g/L; Immunoglobulin M 0.44 g/L; Beta 2 Microglobulin 1.81 µg/mL; Hemoglobin 7.25 mmol/L; Leukocytes 6.3 ×10⁹/L; Absolute Neutrophil 4.4 ×10⁹/L; Platelets 272 ×10⁹/L.
- Day 638 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.908 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.26 mg/dL; Immunoglobulin G 9.76 g/L; Immunoglobulin A 1.19 g/L; Immunoglobulin M 0.78 g/L; Lactate Dehydrogenase 3.28 µkat/L; Hemoglobin 8 mmol/L; Leukocytes 8.4 ×10⁹/L; Absolute Neutrophil 5.6 ×10⁹/L; Platelets 296 ×10⁹/L; Creatinine 63.6 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.43 mmol/L; Albumin 50 g/L; Total Protein 7.2 g/dL; Glucose 3.96 mmol/L.
- Day 700 (ECOG 1): M Protein 0.18 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.787 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.08 mg/dL; Immunoglobulin G 9.92 g/L; Immunoglobulin A 1.04 g/L; Immunoglobulin M 0.71 g/L; Lactate Dehydrogenase 2.88 µkat/L; Hemoglobin 7.94 mmol/L; Leukocytes 7.1 ×10⁹/L; Absolute Neutrophil 4.4 ×10⁹/L; Platelets 276 ×10⁹/L; Creatinine 67.2 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.33 mmol/L; Albumin 45 g/L; Total Protein 6.8 g/dL; Glucose 4.24 mmol/L.
- Day 826 (ECOG 1): M Protein 0.19 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.3 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.47 mg/dL; Immunoglobulin G 10.6 g/L; Immunoglobulin A 1.15 g/L; Immunoglobulin M 0.87 g/L; Lactate Dehydrogenase 3.08 µkat/L; Hemoglobin 7.5 mmol/L; Leukocytes 7.4 ×10⁹/L; Absolute Neutrophil 5 ×10⁹/L; Platelets 349 ×10⁹/L; Creatinine 61.9 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.2 mmol/L; Albumin 44 g/L; Total Protein 7 g/dL; Glucose 5.06 mmol/L.
- Day 918 (ECOG 1): M Protein 0.24 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.78 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.01 mg/dL; Immunoglobulin G 12 g/L; Immunoglobulin A 1.34 g/L; Immunoglobulin M 0.94 g/L; Lactate Dehydrogenase 2.83 µkat/L; Hemoglobin 8.18 mmol/L; Leukocytes 6.4 ×10⁹/L; Absolute Neutrophil 4.5 ×10⁹/L; Platelets 311 ×10⁹/L; Creatinine 66.3 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.45 mmol/L; Albumin 45 g/L; Total Protein 7.5 g/dL; Glucose 4.46 mmol/L.
- Day 1,009 (ECOG 1): M Protein 0.2 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.2 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.36 mg/dL; Immunoglobulin G 12 g/L; Immunoglobulin A 1.25 g/L; Immunoglobulin M 0.83 g/L; Lactate Dehydrogenase 2.47 µkat/L; Hemoglobin 8.56 mmol/L; Leukocytes 5.9 ×10⁹/L; Absolute Neutrophil 3.6 ×10⁹/L; Platelets 236 ×10⁹/L; Creatinine 69.8 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.25 mmol/L; Albumin 46 g/L; Total Protein 7.3 g/dL; Glucose 4.29 mmol/L.
- Day 1,101 (ECOG 1): M Protein 0.18 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.54 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.32 mg/dL; Immunoglobulin G 11 g/L; Immunoglobulin A 1.35 g/L; Immunoglobulin M 0.69 g/L; Lactate Dehydrogenase 2.73 µkat/L; Hemoglobin 8 mmol/L; Leukocytes 7.9 ×10⁹/L; Absolute Neutrophil 5.2 ×10⁹/L; Platelets 349 ×10⁹/L; Creatinine 84.9 µmol/L; Blood Urea Nitrogen 3.93 mmol/L; Calcium 2.2 mmol/L; Albumin 44 g/L; Total Protein 7.3 g/dL; Glucose 5.12 mmol/L.
- Day 1,192 (ECOG 1): M Protein 0.21 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.35 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.23 mg/dL; Immunoglobulin G 11.8 g/L; Immunoglobulin A 1.48 g/L; Immunoglobulin M 0.83 g/L; Lactate Dehydrogenase 3.17 µkat/L; Hemoglobin 7.87 mmol/L; Leukocytes 5.2 ×10⁹/L; Absolute Neutrophil 3.1 ×10⁹/L; Platelets 237 ×10⁹/L; Creatinine 77.8 µmol/L; Blood Urea Nitrogen 7.14 mmol/L; Calcium 2.38 mmol/L; Albumin 46 g/L; Total Protein 7.3 g/dL; Glucose 5.12 mmol/L.
- Day 1,283 (ECOG 1): M Protein 0.25 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.32 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.18 mg/dL; Immunoglobulin G 12.4 g/L; Immunoglobulin A 1.49 g/L; Immunoglobulin M 0.9 g/L; Lactate Dehydrogenase 2.88 µkat/L; Hemoglobin 8.37 mmol/L; Leukocytes 7.5 ×10⁹/L; Absolute Neutrophil 4.6 ×10⁹/L; Platelets 248 ×10⁹/L; Creatinine 76.9 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.33 mmol/L; Albumin 45 g/L; Total Protein 7.3 g/dL; Glucose 4.46 mmol/L.
- Day 1,374 (ECOG 1): M Protein 0.36 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.49 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.78 mg/dL; Immunoglobulin G 14.3 g/L; Immunoglobulin A 1.65 g/L; Immunoglobulin M 0.79 g/L; Lactate Dehydrogenase 2.97 µkat/L; Hemoglobin 7.87 mmol/L; Leukocytes 6.8 ×10⁹/L; Absolute Neutrophil 4.1 ×10⁹/L; Platelets 243 ×10⁹/L; Creatinine 64.5 µmol/L; Blood Urea Nitrogen 3.93 mmol/L; Calcium 2.4 mmol/L; Albumin 46 g/L; Total Protein 7.4 g/dL; Glucose 5.06 mmol/L.
- Day 1,430 (ECOG 1): M Protein 0.43 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.33 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.6 mg/dL; Immunoglobulin G 15 g/L; Immunoglobulin A 1.71 g/L; Immunoglobulin M 0.9 g/L; Lactate Dehydrogenase 2.85 µkat/L; Hemoglobin 7.87 mmol/L; Leukocytes 5.8 ×10⁹/L; Absolute Neutrophil 3.2 ×10⁹/L; Platelets 229 ×10⁹/L; Creatinine 61.9 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.45 mmol/L; Albumin 45 g/L; Total Protein 7.6 g/dL; Glucose 4.57 mmol/L.

Other clinical attributes
- Day 1: Weight: 53 kg; Height: 147 cm.

Family history
- Relative with cancer history: no.

Biospecimens (2 samples)
- Sample MMRF_1408_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: 1 day.
- Sample MMRF_1408_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: 1 day.
